CCDI case PBCPKK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Spinal cord, cranial nerves, and other parts of central nervous system.
https://portal.gdc.cancer.gov/cases/587f7cda-16bd-4bea-9142-64dbf3bca741

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Spinal cord; Age at diagnosis: 12.8 years (4,663 days).

Biospecimens (3 samples)
- Sample 0DWNR8: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DWNSX: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DWNTX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
